Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9I1, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9I1-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Final Diagnosis

- A. PORTION OF UTERUS:
Uterine leiomyosarcoma, high-grade.
Tumor measures 10 x 6 x 5.5 cm.
Tumor focally extends to uterine serosa.
Focal angiolymphatic invasion present.
Ovary with physiologic changes.
Fallopian tube with no significant pathologic changes.
- B. REMAINING PORTION OF UTERUS, BILATERAL TUBES AND OVARIES:
Uterine leiomyosarcoma, high-grade.
Tumor involves wall of the cervix.
Tumor focally involves uterine serosa.
Tumor measures 18 x 9 x 9 cm.
Inactive type endometrium.
Adenomyosis.
Ovary with physiologic changes.
Fallopian tube: Negative for malignancy.
- C. PORTION OF OMENTUM:
Benign omental adipose tissue.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by _____

Comment

The pathologic stage, based on the above information, is best classified as T1b NX MX.

Specimen(s) Received

- A PORTION OF UTERUS
B REMAINING PORTION OF UTERUS BILATERAL TUBES AND OVARIES
C PORTION OF OMENTUM

Clinical History

- A year-old female with uterine leiomyosarcoma.

Preoperative Diagnosis

Leiomyosarcoma.

Gross Description

ICD-O.3
Leiomyosarcoma NOS 8890/3
Site: Uterus NOS C55.9
JW 4/22/14

[page 2 of 3]
A. Specimen A is received fresh labeled "portion of uterus." The specimen consists of an irregular, unoriented portion of uterine body measuring 10.5 x 8.5 x 6.5 cm, weighing 310 g. Serosa is variegated pink-tan to dusky red, focally hemorrhagic, and bosselated. The specimen is subtotally replaced by tan to gray, rubbery, focally hemorrhagic and necrotic tumor which measures 10. x 6 x 5.5 cm. The tumor bulges but does not appear to extend through the serosa. The cut surface of the tumor is pink-tan, homogeneous, focally hemorrhagic, and necrotic. The areas of hemorrhage and necrosis occupy less than 10% of the tumor. Also received in the same container is an unoriented ovary 2.49 (3.5 x 1.5 x 0.9 cm, weighing 4.3 g) with attached fimbriated fallopian tube (5.0 cm in length and 0.4 cm in greatest diameter). The surface of the ovary is tan, cribriform. On sectioning, the ovary reveals a grossly unremarkable ovarian parenchyma. The serosa covering the fallopian tube is dusky red, smooth, and glistening. On sectioning, the fallopian tube reveals a pinpoint, grossly unremarkable lumen. Also received in the same container are multiple irregular, unoriented fragments of pink-tan to gray, focally hemorrhagic, rubbery tissue consistent with potential tumor which measures 6 x 6 x 3 cm in aggregate and weighs 55 g. Representative sections of the specimen are submitted to the

follows:

- A1: Ovary.
- A2: Fallopian tube.
- A3-A8: Representative sections of the portion of uterus with overlying serosa.
- A9-A12: Representative sections of the free-floating fragments of tissue.

B. Specimen B is received fresh labeled "remaining portion of uterus, bilateral tubes, and ovaries." The specimen consists of an enlarged and distorted by the tumor uterus which measures 18 cm from proximal to distal, 9.5 cm transversely, and up to 10.4 cm from anterior to posterior. Attached to the uterus is a white ovary (3 x 2 x 1 cm weighing 5.0 g) and a right fimbriated fallopian tube (5.5 cm in length and up to 0.4 cm in diameter). The surface of the right ovary is pink-tan, smooth and glistening. On sectioning, the ovary reveals grossly unremarkable ovarian parenchyma. The right fallopian tube reveals an area of ligation. The portions of fallopian tube adjacent to the this area are grossly unremarkable and reveal a pinpoint, grossly unremarkable lumen. There is a small portion of left fallopian tube attached to the uterus measuring 1.0 cm in length and 0.3 cm in diameter. There is an irregular serosal and mural defect on the posterior aspect of the uterine body measuring 10 x 5 x 3 cm, weighing 1210 g. This area is consistent with the portion of uterus received in container A. The remaining uterine body is covered by pink-tan, congested, smooth, and glistening serosa. Prior to sectioning, the specimen is inked as follows:

- Anterior aspect of the uterus and cervix: Black.
- Posterior: Blue.

On sectioning, the uterus reveals an irregular, ill-defined, rubbery solid tumor which measures 18 x 9 x 9 cm. The tumor involves anterior and posterior myometrium, lower uterine segment, and cervix and extends to within 0.1 cm of the radial cervical resection margin. The tumor bulges in the cervical mucosa and endometrium and partially adjacent but does not appear to extend through the serosa covering the uterine body. The endocervical canal and endometrial canal cavity are distorted by the tumor. The endocervical canal measures 5.5 cm in length and ranges from 0.3 to 0.8 cm diameter. The endometrial cavity up to 7 x 3.5 x 0.5 cm and exhibits pink-tan, focally hemorrhagic endometrium which measures 0.1 cm in thickness. The cut surface of the tumor is pink-tan to gray, focally hemorrhagic and necrotic. The areas of necrosis and hemorrhage occupy less than 10% of the tumor. The remaining myometrium is tan, trabeculated, and ranges from 0.5 to 1.5 cm in thickness. The tumor also extends to within 0.3 cm of the closest radial resection margin of the cervix. No tissue was submitted to the

Representative sections of the specimen are submitted in 20 cassettes as follows:

[page 3 of 3]
B1: Right ovary.
B2: Right fallopian tube.
B3: The portion of left fallopian tube.
B4: Anterior cervix.
B5: Posterior cervix.
B6-B7: Sections of the anterior aspect of the proximal cervix involved by the tumor.
B8-B9: Cross sections of the posterior aspect of the proximal cervix involved by the tumor.
B10-B11: Additional sections of the tumor in relation to the closest posterior aspect of the radial resection margin of the cervix.
B12-B13: Anterior endomyometrium.
B14: Posterior endomyometrium.
B15-B20: Addition sections of the tumor.

C. Specimen C is received fresh labeled "portion of omentum." The specimen consists of an irregular, unoriented portion of omental adipose tissue measuring 12 x 8 and ranges from 0.3 to 1.0 cm in thickness. There are multiple subserosal foci of hemorrhage which range from 0.1 to 0.5 cm in greatest dimension. No tumor or other lesions are grossly identified. Representative sections of the specimen are submitted in 4 cassettes, C1-C4.

hu 1/2/14
12/2/13

Source: NCI Genomic Data Commons file 75f9a027-a4aa-4c3f-b767-9c8cb497ed94 (TCGA-3B-A9I1.A6AA7DD4-7FD4-4EE9-8F26-D85F72C0C717.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).